Somatic mutation profile of tumor specimen TCGA-49-4505-01A (aliquot TCGA-49-4505-01A-01D-1931-08) from TCGA case TCGA-49-4505, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.0 years (22,628 days).
Specimen TCGA-49-4505-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73fcb0f6-6a7b-408c-8690-acaac02e872e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-4505-11A (Solid Tissue Normal), aliquot TCGA-49-4505-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f4fa07e-188c-40a4-9c26-a5cca27767b4

The open-access MAF lists 231 somatic variants for this specimen: 169 protein-altering or splice-affecting, 56 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 56, Nonsense Mutation 8, Splice Site 5, Frame Shift Del 4, Intron 3, Frame Shift Ins 2, In Frame Ins 1, In Frame Del 1, RNA 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 31/64 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA3 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as rs150902383, COSV100068861; called by muse, mutect2, varscan2
- ACAN | c.6701T>C p.L2234P | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV100718699; called by muse, mutect2, varscan2
- ACTN2 | c.559T>A p.C187S | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV100856896; called by muse, mutect2, varscan2
- ADAMTS18 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs200297898, COSV99273542, COSV99274550; called by muse, mutect2
- ADGRG4 | c.8482G>T p.G2828C | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV99796088; called by muse, mutect2, varscan2
- ADIPOR1 | c.739A>C p.I247L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV100579593; called by muse, mutect2, varscan2
- ADRA1D | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs759163733, COSV65241170; called by muse, mutect2
- ALDH1B1 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1402870403, COSV100890963; called by muse, mutect2, varscan2
- ALDH1B1 | c.200A>T p.H67L | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100890964; called by muse, mutect2, varscan2
- ANK2 | c.9281C>A p.P3094Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100002885; called by muse, mutect2, varscan2
- ARHGEF1 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as rs1555847368, COSV61528804; called by muse, mutect2
- ARSF | c.1346G>T p.C449F | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100839553; called by muse, mutect2, varscan2
- BCR | c.2528G>T p.S843I | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV100006755; called by muse, mutect2, varscan2
- CA4 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs201580764, COSV99958440; called by muse, mutect2, varscan2
- CACNA2D1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.03); catalogued as COSV100666952; called by muse, mutect2, varscan2
- CCHCR1 | c.1472G>T p.S491I | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV100885682; called by muse, mutect2
- CD4 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99163839; called by muse, mutect2, varscan2
- CDKN2A | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.426); catalogued as COSV100447224, COSV58698822, COSV58727809; called by muse, mutect2
- CELSR3 | c.5777C>T p.S1926F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99374274; called by muse, mutect2, varscan2
- CLEC16A | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201076792, COSV55491109; called by muse, mutect2, varscan2
- CNOT6 | c.113-2A>G p.X38_splice | Splice Site (SNP) | VAF 140/380 reads (37%) | catalogued as COSV99993674; called by muse, mutect2, varscan2
- COG4 | c.1807A>G p.K603E | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV99851106; called by muse, mutect2, varscan2
- COL7A1 | c.5604+1G>A p.X1868_splice | Splice Site (SNP) | VAF 25/130 reads (19%) | catalogued as CS142925, COSV100096940; called by muse, mutect2, varscan2
- CSMD1 | c.6694C>A p.Q2232K (on ENST00000520002; = p.Q2231K on NM_033225.6) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs759144707, COSV100150982; called by mutect2, varscan2
- CTNND2 | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 47/464 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100478996; called by muse, mutect2, varscan2
- CUBN | c.1786G>T p.G596C | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV64714496; called by muse, mutect2, varscan2
- CUL1 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57388725; called by muse, mutect2
- CYBB | c.1083G>T p.W361C | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM015939, COSV101059792; called by muse, mutect2, varscan2
- DIS3L2 | c.2010G>T p.Q670H | Missense Mutation (SNP) | VAF 98/348 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99806828; called by muse, mutect2, varscan2
- DNAJC10 | c.849+1del | Frame Shift Del (DEL) | VAF 62/265 reads (23%) | catalogued as COSV99899643; called by mutect2, pindel, varscan2
- DRD5 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.267); catalogued as rs1365672576, COSV100431918; called by muse, mutect2, varscan2
- EEF2 | c.2503G>T p.V835L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV58580818; called by muse, mutect2, varscan2
- ELAVL3 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100820811; called by muse, mutect2, varscan2
- ENPEP | c.2689G>T p.E897* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as COSV99487859; called by muse, mutect2, varscan2
- EPHA7 | c.2111G>T p.G704V | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100994002, COSV100994207; called by muse, mutect2, varscan2
- FAM135B | c.43C>A p.H15N | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV99357684; called by muse, mutect2, varscan2
- FAM13C | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99514250; called by muse, mutect2, varscan2
- FAM47B | c.574C>G p.P192A | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV100264471; called by muse, mutect2, varscan2
- FAT3 | c.12196C>T p.P4066S | Missense Mutation (SNP) | VAF 140/401 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV99968062; called by muse, mutect2, varscan2
- FBXL7 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100310295; called by muse, mutect2
- FBXO38 | c.2831A>T p.D944V (on ENST00000340253 / NM_205836.3; = p.D869V on NM_030793.5) | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99693684; called by muse, mutect2, varscan2
- FGD3 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1413469101, COSV100490393; called by muse, mutect2, varscan2
- FGD5 | c.3859G>A p.D1287N | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.198); catalogued as rs762517672, COSV99548656; called by muse, mutect2
- GGT5 | c.1256G>T p.R419L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV54071942, COSV99571445; called by muse, mutect2, varscan2
- GLIPR1 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99875776; called by muse, mutect2, varscan2
- GP2 | c.1433C>A p.S478* (on ENST00000381362 / NM_001007240.3; = p.S475* on NM_001502.4) | Nonsense Mutation (SNP) | VAF 46/153 reads (30%) | catalogued as rs140017290; called by muse, mutect2, varscan2
- GPR149 | c.103T>A p.Y35N | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV101078576; called by muse, mutect2, varscan2
- GRIN2A | c.4355G>A p.R1452H | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.998); catalogued as rs774039446, COSV58020621; ClinVar: uncertain significance; called by muse, mutect2
- GRM5 | c.2262C>A p.C754* | Nonsense Mutation (SNP) | VAF 80/236 reads (34%) | catalogued as COSV100553209; called by muse, mutect2, varscan2
- H1-4 | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99175307; called by muse, mutect2, varscan2
- HAND2 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64018496; called by muse, mutect2
- HCLS1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.518); catalogued as COSV100100924; called by muse, mutect2, varscan2
- HCN1 | c.2599C>A p.L867I | Missense Mutation (SNP) | VAF 76/345 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.029); catalogued as COSV100301315, COSV57516836; called by muse, mutect2, varscan2
- HDC | c.1243-2A>T p.X415_splice | Splice Site (SNP) | VAF 34/95 reads (36%) | catalogued as COSV99984191; called by muse, mutect2, varscan2
- HMGA2 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100666597; called by muse, mutect2, varscan2
- HTATSF1 | c.2095G>T p.D699Y | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV99511779; called by muse, mutect2, varscan2
- IGKV3D-11 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 123/302 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs779713839; called by muse, mutect2, varscan2
- IL17A | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as COSV60685796; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1711C>A p.Q571K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as rs756892831, COSV100148575; called by muse, mutect2, varscan2
- INHBA | c.1276T>A p.S426T | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV54221962; called by muse, mutect2
- INPP4B | c.2230G>C p.V744L | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV99525591; called by muse, mutect2, varscan2
- IP6K3 | c.258C>G p.N86K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as rs370358888; called by muse, mutect2, varscan2
- ITGB1 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100171841; called by muse, mutect2, varscan2
- ITPR2 | c.6430A>T p.N2144Y | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV101190078; called by muse, mutect2, varscan2
- KAT7 | c.1765G>T p.A589S | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.023); catalogued as rs1290786510, COSV52016189; called by muse, mutect2, varscan2
- KATNIP | c.1163A>T p.K388M | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV99851568; called by muse, mutect2, varscan2
- KIF18A | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1490340368, COSV99588923; called by muse, mutect2, varscan2
- KL | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV101199153; called by muse, mutect2, varscan2
- KRTAP5-10 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 89/281 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); catalogued as COSV100924142, COSV100924152; called by muse, mutect2, varscan2
- LARP1 | c.443C>T p.S148F (on ENST00000518297 / NM_033551.3; = p.S71F on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV100303937; called by muse, mutect2, varscan2
- LGR6 | c.2217G>T p.M739I (on ENST00000367278 / NM_001017403.1; = p.M687I on NM_021636.3) | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV99706015, COSV99707465; called by muse, mutect2, varscan2
- LHX8 | c.681A>T p.R227S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99634055; called by muse, mutect2, varscan2
- LINS1 | c.834G>T p.L278F | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100130376; called by muse, mutect2
- LTBP2 | c.124A>T p.R42* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100000683; called by muse, mutect2, varscan2
- LUZP2 | c.333+1G>T p.X111_splice | Splice Site (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100420576, COSV61194130; called by muse, mutect2, varscan2
- MDN1 | c.533G>T p.S178I | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV101021568; called by muse, mutect2, varscan2
- MED1 | c.3385A>G p.S1129G | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100327982; called by muse, mutect2, varscan2
- MKI67 | c.8680G>T p.D2894Y | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100896813; called by muse, mutect2, varscan2
- MMP2 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 24/172 reads (14%) | catalogued as rs760625271, COSV54604188, COSV54606885; called by muse, mutect2, varscan2
- MORC3 | c.1040T>C p.I347T | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV101264990; called by muse, mutect2, varscan2
- MROH2B | c.2096C>A p.T699K | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV101270822; called by muse, mutect2, varscan2
- MS4A14 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100280588, COSV100280653; called by muse, mutect2
- MTMR2 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs775237206, COSV100656783; called by muse, mutect2, varscan2
- MUC17 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 36/421 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100074278; called by muse, mutect2
- MYH2 | c.5539C>G p.R1847G | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV55431381, COSV99820558; called by muse, mutect2, varscan2
- MYOM3 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as rs199782500; called by muse, mutect2, varscan2
- NAV3 | c.1046C>A p.T349N | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV99893352; called by muse, mutect2, varscan2
- NCKAP5 | c.3761C>A p.S1254Y | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100493376; called by muse, mutect2, varscan2
- NCOA6 | c.1831G>T p.G611C | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62867246, COSV62868189; called by muse, mutect2, varscan2
- NCOR2 | c.6508G>T p.V2170F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100657659; called by muse, mutect2
- NDUFS1 | c.1810C>T p.Q604* | Nonsense Mutation (SNP) | VAF 52/176 reads (30%) | catalogued as COSV99261041; called by muse, mutect2, varscan2
- NLRP5 | c.2201G>C p.R734P | Missense Mutation (SNP) | VAF 128/332 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV101173528, COSV66762506, COSV66765656; called by muse, mutect2, varscan2
- NSD2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100373627; called by muse, mutect2, varscan2
- NXF5 | n.841-1G>T | Splice Site (SNP) | VAF 14/77 reads (18%) | catalogued as COSV99534516; called by muse, mutect2, varscan2
- OR2L2 | c.408C>A p.S136R | Missense Mutation (SNP) | VAF 92/369 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs1287727845, COSV100824098; called by muse, mutect2, varscan2
- OR4A15 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as rs199660751, COSV59033672; called by muse, mutect2, varscan2
- OR51I2 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100413253, COSV100413433; called by muse, mutect2, varscan2
- OR56B4 | c.242C>A p.T81N | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100337678; called by mutect2, varscan2
- OR5B2 | c.793T>G p.S265A | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.168); catalogued as COSV100222918, COSV56907956; called by muse, mutect2, varscan2
- OR6N2 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 118/357 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1282610884, COSV100210288, COSV100210443; called by muse, mutect2, varscan2
- PADI3 | c.1498T>C p.F500L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100968527; called by muse, mutect2, varscan2
- PCDH11X | c.2962C>A p.P988T | Missense Mutation (SNP) | VAF 109/220 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV100013301, COSV53503039; called by muse, mutect2, varscan2
- PCDH15 | c.4640G>C p.R1547T | Missense Mutation (SNP) | VAF 88/264 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs1264102175, COSV100905160, COSV64722175; called by muse, mutect2, varscan2
- PCDH15 | c.3503C>A p.A1168D | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57271516; called by muse, mutect2, varscan2
- PCDHB8 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 96/788 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.044); catalogued as COSV50754429; called by muse, mutect2, varscan2
- PCLO | c.10340C>T p.T3447M | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs942302843, COSV61660184; called by muse, mutect2, varscan2
- PDE1A | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV100115339; called by muse, mutect2, varscan2
- PEAK3 | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV100457371, COSV59233651; called by muse, mutect2, varscan2
- POTEH | c.605A>T p.D202V | Missense Mutation (SNP) | VAF 23/342 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs763204641, COSV100625097; called by muse, varscan2
- POU1F1 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100622732; called by muse, mutect2, varscan2
- PRDM14 | c.1688C>A p.S563Y | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99400346; called by muse, mutect2, varscan2
- PRKAG2 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV99835640; called by muse, mutect2, varscan2
- PSG11 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 93/441 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100105996; called by muse, mutect2, varscan2
- PSG7 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.138); catalogued as COSV101343293; called by muse, mutect2, varscan2
- PTH | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99961709; called by muse, mutect2, varscan2
- PTPN13 | c.7159G>A p.D2387N (on ENST00000411767 / NM_080683.3; = p.D2368N on NM_006264.3) | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.615); catalogued as rs750738215, COSV100364259, COSV100365134; called by muse, mutect2, varscan2
- RABL3 | c.457C>G p.H153D | Missense Mutation (SNP) | VAF 99/532 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.044); catalogued as rs371895451, COSV56336944, COSV99846589; called by muse, mutect2, varscan2
- RAPGEF1 | c.2229C>A p.F743L | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV64701936; called by muse, mutect2, varscan2
- RBBP6 | c.4454C>A p.S1485Y | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.44); catalogued as COSV100154745; called by muse, mutect2, varscan2
- RCOR3 | c.297A>T p.Q99H | Missense Mutation (SNP) | VAF 78/391 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100879636; called by muse, mutect2, varscan2
- RET | c.1049C>A p.T350N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV100394057; called by muse, mutect2, varscan2
- RNF145 | c.1040T>G p.F347C (on ENST00000424310 / NM_001199383.2; = p.F375C on NM_144726.2) | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99193733; called by muse, mutect2
- RRAS2 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as rs571234555, COSV99819137; called by muse, mutect2, varscan2
- RUNX1T1 | c.1607G>T p.G536V (on ENST00000265814 / NM_001198628.1; = p.G509V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99753427; called by muse, mutect2, varscan2
- RYR2 | c.5195A>G p.E1732G | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as COSV100771941; called by muse, mutect2
- RYR2 | c.10373G>T p.R3458L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV100768952, COSV100771942; called by muse, mutect2, varscan2
- SAMD7 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373905806, COSV100156992; called by muse, mutect2, varscan2
- SCN10A | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 55/295 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV101479471; called by muse, mutect2, varscan2
- SERPINA11 | c.57T>A p.C19* | Nonsense Mutation (SNP) | VAF 37/224 reads (17%) | catalogued as COSV100594091; called by muse, mutect2, varscan2
- SESTD1 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100090692; called by muse, mutect2, varscan2
- SI | c.2300C>T p.S767F | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs752951766, COSV100016391; called by muse, mutect2
- SLC34A2 | c.1108A>T p.I370L | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV101158426; called by muse, mutect2, varscan2
- SLIT3 | c.2770C>A p.P924T | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100268804; called by muse, mutect2
- SNTG1 | c.104T>A p.I35N | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV99384860; called by muse, mutect2, varscan2
- SORBS1 | c.1066G>C p.E356Q (on ENST00000361941 / NM_001034954.2; = p.E192Q on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV99528519; called by muse, mutect2, varscan2
- SOX11 | c.710T>A p.L237Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs1226706343, COSV100431292; called by muse, varscan2
- SSPN | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 31/568 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs761742193, COSV99658765; called by muse, mutect2
- STK31 | c.1682G>T p.S561I | Missense Mutation (SNP) | VAF 119/437 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV100669692; called by muse, mutect2, varscan2
- STXBP5L | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99871347; called by muse, mutect2, varscan2
- SV2C | c.1819A>G p.I607V | Missense Mutation (SNP) | VAF 101/276 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as rs1171062171, COSV100456507; called by muse, mutect2, varscan2
- SVEP1 | c.5096G>T p.G1699V | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99928943, COSV99929398; called by muse, mutect2, varscan2
- TAAR2 | c.441C>A p.Y147* (on ENST00000367931 / NM_001033080.1; = p.Y102* on NM_014626.3) | Nonsense Mutation (SNP) | VAF 43/130 reads (33%) | catalogued as COSV99255710; called by muse, mutect2, varscan2
- TAS1R2 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV100946290, COSV64743966; called by muse, mutect2, varscan2
- TAS2R60 | c.344G>T p.S115I | Missense Mutation (SNP) | VAF 60/388 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100223606; called by muse, mutect2, varscan2
- TMPRSS11D | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 22/454 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as COSV99384844; called by muse, mutect2
- TRAPPC12 | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100160751; called by muse, mutect2, varscan2
- TRPM6 | c.3955A>T p.R1319W | Missense Mutation (SNP) | VAF 51/375 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as COSV100666679; called by muse, mutect2, varscan2
- TTN | c.26326G>A p.V8776I (on ENST00000591111; = p.V7849I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/152 reads (31%) | PolyPhen benign (0.012); catalogued as COSV60045095; called by muse, mutect2, varscan2
- TXLNG | c.1136G>C p.R379T | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101200593; called by muse, mutect2
- UGT2B17 | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 92/604 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.468); catalogued as COSV100497258; called by muse, mutect2, varscan2
- UGT3A1 | c.1312G>T p.V438L | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV99955060; called by muse, mutect2, varscan2
- UNC80 | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.634); catalogued as COSV99780202; called by muse, mutect2, varscan2
- WT1 | c.1228C>A p.Q410K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.063); catalogued as COSV100188525; called by muse, mutect2, varscan2
- ZFHX4 | c.4970C>A p.A1657D | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV99265253; called by muse, mutect2, varscan2
- ZFPM2 | c.766G>T p.G256C | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101023313, COSV65874828; called by muse, varscan2
- ZIC1 | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.115); catalogued as rs1243038866, COSV51555517, COSV51556362; called by muse, mutect2, varscan2
- ZNF282 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as rs1302630940, COSV100021563, COSV100021774; called by muse, mutect2
- ZNF334 | c.1038G>T p.E346D | Missense Mutation (SNP) | VAF 80/400 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV100749142; called by muse, mutect2, varscan2
- ZNF385D | c.458C>A p.P153Q | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99875564; called by muse, mutect2, varscan2
- CFAP54 | c.5376_5401del p.L1793Gfs*13 | Frame Shift Del (DEL) | VAF 40/272 reads (15%) | called by mutect2, pindel
- DOCK9 | c.936del p.D312Efs*18 (on ENST00000376460 / NM_001366676.2; = p.D313Efs*18 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by pindel, varscan2
- IGHG1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 137/726 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- KCNG4 | c.542_554del p.E181Gfs*20 | Frame Shift Del (DEL) | VAF 15/127 reads (12%) | called by mutect2, pindel
- LORICRIN | c.80_81insTTGCGG p.G27_G28insCG | In Frame Ins (INS) | VAF 9/42 reads (21%) | called by mutect2, varscan2
- MYCBPAP | c.2196_2202dup p.E735Pfs*41 | Frame Shift Ins (INS) | VAF 70/209 reads (33%) | called by mutect2, varscan2
- OR52R1 | c.865dup p.M289Nfs*10 | Frame Shift Ins (INS) | VAF 55/299 reads (18%) | called by mutect2, pindel, varscan2
- TMEM175 | c.234_248del p.I78_L82del | In Frame Del (DEL) | VAF 48/178 reads (27%) | called by mutect2, pindel, varscan2
- AFF2 | c.3120G>A p.L1040= | Silent (SNP) | VAF 31/389 reads (8%) | catalogued as COSV99665155; called by muse, mutect2
- ALOX5 | c.1278C>T p.N426= | Silent (SNP) | VAF 9/197 reads (5%) | catalogued as rs537072496, COSV100980120; called by muse, mutect2
- BIVM-ERCC5 | c.405C>T p.G135= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV99958930; called by muse, mutect2
- BRD1 | c.1764G>C p.A588= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99350010; called by muse, mutect2
- BTBD11 | c.1236C>A p.T412= | Silent (SNP) | VAF 35/229 reads (15%) | catalogued as COSV99776419; called by muse, mutect2, varscan2
- BTN1A1 | c.1485C>A p.I495= | Silent (SNP) | VAF 65/372 reads (17%) | catalogued as COSV99764481; called by muse, mutect2, varscan2
- CPN2 | c.1377G>A p.P459= | Silent (SNP) | VAF 28/322 reads (9%) | catalogued as rs373278468; called by muse, mutect2
- DACH1 | c.1488C>T p.P496= (on ENST00000619232 / NM_001366712.1; = p.P444= on NM_080759.6) | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs1006642131, COSV100498778; called by muse, mutect2, varscan2
- DCAF7 | c.429G>T p.T143= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV100177703; called by muse, mutect2, varscan2
- DGUOK | c.192A>G p.E64= | Silent (SNP) | VAF 32/205 reads (16%) | catalogued as COSV99903589; called by muse, mutect2, varscan2
- DICER1 | c.5607G>T p.P1869= | Silent (SNP) | VAF 143/436 reads (33%) | catalogued as COSV100602305; called by muse, mutect2, varscan2
- EEF2 | c.2502G>T p.V834= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100500850; called by muse, mutect2, varscan2
- EHD2 | c.1119G>T p.S373= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99622082; called by muse, mutect2, varscan2
- EPHB6 | c.738G>T p.T246= | Silent (SNP) | VAF 116/303 reads (38%) | catalogued as COSV101235986, COSV67421606; called by muse, mutect2, varscan2
- ESCO1 | c.2505T>C p.N835= | Silent (SNP) | VAF 22/193 reads (11%) | catalogued as COSV99332442; called by muse, mutect2, varscan2
- FAT4 | c.12072G>C p.R4024= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as COSV100628157; called by muse, mutect2, varscan2
- FBXO47 | c.1035G>T p.V345= | Silent (SNP) | VAF 81/195 reads (42%) | catalogued as COSV100960791; called by muse, mutect2, varscan2
- GALNTL6 | c.876C>A p.I292= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as COSV101560007; called by muse, mutect2, varscan2
- GFPT2 | c.1611G>T p.T537= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99517900; called by muse, mutect2, varscan2
- GFRA1 | c.480C>A p.A160= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100815873; called by muse, mutect2, varscan2
- HFM1 | c.2178C>A p.I726= | Silent (SNP) | VAF 28/181 reads (15%) | catalogued as COSV99646351; called by muse, mutect2, varscan2
- HMCN1 | c.14928G>T p.R4976= | Silent (SNP) | VAF 93/325 reads (29%) | catalogued as COSV99625803; called by muse, mutect2, varscan2
- HRH2 | c.783G>A p.G261= | Silent (SNP) | VAF 13/294 reads (4%) | catalogued as COSV99199765; called by muse, mutect2
- IFNA8 | c.201T>C p.D67= | Silent (SNP) | VAF 66/216 reads (31%) | catalogued as COSV101206917; called by muse, mutect2, varscan2
- IGF2BP1 | c.27C>T p.L9= | Silent (SNP) | VAF 43/240 reads (18%) | catalogued as COSV51731377; called by muse, mutect2, varscan2
- INTS1 | c.1686C>T p.I562= | Silent (SNP) | VAF 16/196 reads (8%) | catalogued as rs770328797, COSV101248150; called by muse, mutect2
- ITGAM | c.642G>C p.L214= | Silent (SNP) | VAF 68/271 reads (25%) | catalogued as COSV99792753; called by muse, mutect2, varscan2
- ITGB8 | c.2034C>A p.S678= | Silent (SNP) | VAF 104/420 reads (25%) | catalogued as COSV99751908; called by muse, mutect2, varscan2
- KCNH1 | c.1770C>A p.L590= (on ENST00000271751 / NM_172362.3; = p.L563= on NM_002238.4) | Silent (SNP) | VAF 61/183 reads (33%) | catalogued as COSV55084836, COSV99660246; called by muse, mutect2, varscan2
- KLHL1 | c.18A>T p.R6= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100917715, COSV64773371; called by muse, mutect2, varscan2
- LAMA3 | c.8823T>A p.S2941= (on ENST00000313654 / NM_198129.4; = p.S1332= on NM_000227.6) | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV99335361; called by muse, mutect2, varscan2
- LSM2 | c.207C>T p.Y69= | Silent (SNP) | VAF 42/594 reads (7%) | catalogued as rs372880853, COSV100989569; called by muse, mutect2
- NUP153 | c.4014C>T p.P1338= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as COSV100020580; called by muse, mutect2, varscan2
- OR2T3 | c.606G>T p.T202= | Silent (SNP) | VAF 98/240 reads (41%) | catalogued as rs1443833489, COSV62082972; called by muse, varscan2
- OR52J3 | c.867C>T p.N289= | Silent (SNP) | VAF 45/175 reads (26%) | catalogued as rs559089699, COSV100984901; called by muse, mutect2, varscan2
- OR5AS1 | c.684C>A p.I228= | Silent (SNP) | VAF 99/331 reads (30%) | catalogued as COSV100546325; called by muse, mutect2, varscan2
- OR5B17 | c.903G>A p.K301= | Silent (SNP) | VAF 62/233 reads (27%) | catalogued as COSV100641934; called by muse, mutect2, varscan2
- OR8U1 | c.744C>A p.V248= | Silent (SNP) | VAF 56/268 reads (21%) | catalogued as COSV100164026, COSV56418098; called by muse, varscan2
- PADI4 | c.51C>A p.A17= | Silent (SNP) | VAF 37/161 reads (23%) | catalogued as rs752860727, COSV100966873; called by muse, mutect2, varscan2
- PDGFRA | c.2946G>C p.V982= | Silent (SNP) | VAF 42/233 reads (18%) | catalogued as COSV57273711, COSV99957167; called by muse, mutect2, varscan2
- PIP4K2C | c.1206T>C p.T402= | Silent (SNP) | VAF 48/241 reads (20%) | catalogued as COSV100533707; called by muse, mutect2, varscan2
- PLEC | c.10482C>T p.L3494= (on ENST00000322810 / NM_201380.4; = p.L3384= on NM_000445.5) | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as rs782511815, COSV59664285; called by muse, mutect2, varscan2
- PLLP | c.57C>G p.A19= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1309522777, COSV99536383; called by muse, mutect2
- RGS7 | c.693T>C p.Y231= | Silent (SNP) | VAF 85/286 reads (30%) | catalogued as COSV100469260; called by muse, mutect2, varscan2
- RYR1 | c.2259C>G p.S753= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs1292606126, COSV100616350; called by muse, mutect2, varscan2
- SCN10A | c.12C>T p.P4= | Silent (SNP) | VAF 38/226 reads (17%) | catalogued as COSV101479472; called by muse, mutect2, varscan2
- SLC4A10 | c.3171T>C p.S1057= (on ENST00000446997 / NM_001354461.2; = p.S1027= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs374324130; called by muse, mutect2
- SLC5A1 | c.43C>A p.R15= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99833592; called by muse, mutect2, varscan2
- SPAG11B | c.105T>A p.A35= | Silent (SNP) | VAF 19/342 reads (6%) | called by muse, mutect2
- TCN1 | c.633A>G p.E211= | Silent (SNP) | VAF 39/251 reads (16%) | catalogued as COSV99953359; called by muse, mutect2, varscan2
- THBS4 | c.372G>T p.R124= | Silent (SNP) | VAF 40/308 reads (13%) | catalogued as COSV100644418, COSV63470450; called by muse, mutect2, varscan2
- TRPC4 | c.1971C>T p.F657= | Silent (SNP) | VAF 38/168 reads (23%) | catalogued as COSV100157344, COSV58998781; called by muse, mutect2, varscan2
- UNC5B | c.1839G>A p.L613= | Silent (SNP) | VAF 62/263 reads (24%) | catalogued as COSV100101011; called by muse, mutect2, varscan2
- VBP1 | c.429G>A p.L143= | Silent (SNP) | VAF 46/194 reads (24%) | catalogued as COSV99660909; called by muse, mutect2, varscan2
- ZNF267 | c.1074C>G p.V358= | Silent (SNP) | VAF 91/408 reads (22%) | catalogued as COSV100339863; called by muse, mutect2, varscan2
- ZNF479 | c.1227C>T p.Y409= | Silent (SNP) | VAF 43/151 reads (28%) | catalogued as COSV100482885; called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 8/65 reads (12%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- AP000769.3 | chr11:65504653 T>C | 5'Flank (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- LINC01098 | n.729T>A | RNA (SNP) | VAF 45/306 reads (15%) | called by muse, mutect2, varscan2
- PLCB4 | c.3460-2194C>A | Intron (SNP) | VAF 39/78 reads (50%) | catalogued as rs760551309, COSV53802026; called by muse, mutect2, varscan2
- PRRC2B | c.6226-920A>G | Intron (SNP) | VAF 79/433 reads (18%) | catalogued as rs757178886, COSV100261078; called by muse, mutect2, varscan2
- ZNF521 | c.-109G>A | 5'UTR (SNP) | VAF 19/133 reads (14%) | catalogued as rs1481124933, COSV100832811; called by muse, mutect2, varscan2
